CCDI case PBBNIJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/abd832d6-1333-44ff-ac72-9aefa2ce4f10

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Myxoid liposarcoma: ICD-O-3 morphology code: 8852/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 18.8 years (6,868 days).

Biospecimens (3 samples)
- Sample 0DH5UC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DH5VF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DH5VN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
